Somatic mutation profile of tumor specimen PCProject_0022_T1_WES (aliquot PCProject_0022_T1_WES_1) from CMI case PCProject_0022, project CMI-MPC: Count Me In (CMI): The Metastatic Prostate Cancer (MPC) Project. Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 41.1 years (15,023 days).
Specimen PCProject_0022_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Prostate; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a28ff513-9918-4297-b18e-653a27f8b69d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen PCProject_0022_SALIVA (Saliva), aliquot PCProject_0022_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/da1c43a1-aa45-4580-af6e-7f94c5c7c521

The open-access MAF lists 42 somatic variants for this specimen: 29 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Intron 4, 5'Flank 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFAP1L1 | c.1096C>T p.R366W | Missense Mutation (SNP) | VAF 130/544 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs374903729; called by muse, mutect2, varscan2
- BCR | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs1220313294, COSV59936145; called by muse, mutect2
- BICRA | c.3416C>T p.T1139M | Missense Mutation (SNP) | VAF 81/323 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.271); catalogued as rs552885093, COSV101194215; called by muse, mutect2, varscan2
- CAMK2G | c.982G>A p.G328S | Missense Mutation (SNP) | VAF 122/527 reads (23%) | SIFT tolerated, low confidence (0.51); PolyPhen probably damaging (0.999); catalogued as rs1426246982; called by muse, mutect2, varscan2
- CHRAC1 | c.383A>C p.E128A | Missense Mutation (SNP) | VAF 26/312 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV99636331; called by muse, mutect2
- COBLL1 | c.3425T>C p.M1142T (on ENST00000392717; = p.M1104T on NM_014900.5) | Missense Mutation (SNP) | VAF 109/456 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs1216828408; called by muse, mutect2, varscan2
- EHD3 | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs138007410; called by muse, mutect2, varscan2
- FAT4 | c.4525C>T p.R1509W | Missense Mutation (SNP) | VAF 119/506 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs200214434, COSV101272246, COSV67880799; called by muse, mutect2, varscan2
- GRID2IP | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70693579; called by muse, mutect2, varscan2
- OR7D4 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 179/644 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142332857, COSV58071798; called by muse, mutect2, varscan2
- RFX1 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 39/181 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.017); catalogued as rs776211108; called by muse, mutect2, varscan2
- SALL1 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 20/378 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057523061, COSV51758602; ClinVar: uncertain significance; called by muse, mutect2
- SLCO6A1 | c.74C>T p.A25V | Missense Mutation (SNP) | VAF 101/399 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV65814761, COSV99059825; called by muse, mutect2, varscan2
- ST8SIA2 | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 160/511 reads (31%) | PolyPhen probably damaging (0.997); catalogued as rs1232323398, COSV51568606; called by muse, mutect2, varscan2
- STIM1 | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 46/574 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs555016539, COSV56153429; called by muse, mutect2
- TLR2 | c.1039A>G p.K347E | Missense Mutation (SNP) | VAF 94/341 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs779986684; called by muse, mutect2, varscan2
- USP46 | c.532A>T p.N178Y | Missense Mutation (SNP) | VAF 87/382 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101484192; called by muse, mutect2, varscan2
- CSTF1 | c.563T>C p.L188P | Missense Mutation (SNP) | VAF 226/930 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCAF4L2 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 153/642 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- ERCC6L2 | c.2161C>A p.P721T | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.091); called by muse, mutect2
- KCNB2 | c.204C>A p.N68K | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- LRRK2 | c.2242-2A>G p.X748_splice | Splice Site (SNP) | VAF 134/531 reads (25%) | called by muse, mutect2, varscan2
- MGAM | c.4555T>G p.W1519G | Missense Mutation (SNP) | VAF 177/832 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NDUFB6 | c.106C>G p.P36A | Missense Mutation (SNP) | VAF 45/182 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6A2 | c.146C>A p.A49E | Missense Mutation (SNP) | VAF 222/971 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- PDE4D | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 25/461 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- TRIP12 | c.4834T>G p.S1612A | Missense Mutation (SNP) | VAF 102/398 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- VPS11 | c.784G>A p.E262K (on ENST00000620429; = p.E806K on NM_021729.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- ZNF251 | c.990T>G p.F330L | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- IGSF10 | c.2688G>T p.L896= | Silent (SNP) | VAF 217/775 reads (28%) | catalogued as rs747595128; called by muse, mutect2, varscan2
- MAGEL2 | c.1806G>A p.T602= | Silent (SNP) | VAF 121/469 reads (26%) | called by muse, mutect2, varscan2
- MSL1 | c.378C>T p.S126= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as rs924206084; called by muse, mutect2
- RCVRN | c.219C>T p.F73= | Silent (SNP) | VAF 77/503 reads (15%) | catalogued as COSV56841020; called by muse, mutect2, varscan2
- RENBP | c.630G>A p.A210= | Silent (SNP) | VAF 14/194 reads (7%) | catalogued as rs373190193, COSV60072839; called by muse, mutect2
- SORCS1 | c.2373G>A p.K791= | Silent (SNP) | VAF 144/618 reads (23%) | catalogued as rs752058347; called by muse, mutect2, varscan2
- TIPRL | c.783C>T p.N261= | Silent (SNP) | VAF 73/389 reads (19%) | catalogued as rs770381679, COSV63209394; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503622 G>C | 5'Flank (SNP) | VAF 51/186 reads (27%) | called by muse, mutect2, varscan2
- DNAH17 | c.8511+2605C>T | Intron (SNP) | VAF 24/168 reads (14%) | catalogued as rs762831568, COSV67751974; called by muse, mutect2, varscan2
- PTPRM | c.2527+233C>T | Intron (SNP) | VAF 114/588 reads (19%) | called by muse, mutect2, varscan2
- STXBP2 | c.578+41del | Intron (DEL) | VAF 35/146 reads (24%) | called by mutect2, pindel, varscan2
- UBE2DNL | n.473C>T | RNA (SNP) | VAF 99/183 reads (54%) | called by muse, mutect2, varscan2
- WDR24 | c.184+44T>A | Intron (SNP) | VAF 24/422 reads (6%) | called by muse, mutect2
